CPTAC case C3N-03025 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4dfaf532-4f41-4720-a7fc-ad8310b24f4f

Demographics
Sex at birth: male; Race: white; Year of birth: 1939; Vital status: Dead; Days to death: 110 days; Year of death: 2018; Country of birth: Poland.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Age at diagnosis: 78.2 years (28,566 days); Year of diagnosis: 2017; Last known disease status: With tumor; Days to last known disease status: 110 days; Days to last follow up: 110 days.
   Pathology details: Greatest tumor dimension: 6 cm.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (1 entry)
- Days to follow up: 110 days; Disease response: With Tumor; Progression or recurrence: Yes; Days to recurrence: 68 days; Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 81 kg; Height: 178 cm; BMI: 25.56.

Exposures
- Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-03025-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -14 days; Initial weight: 201 mg; Time between excision and freezing: 5 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-03025-21: Section location: Right Hemisphere; Percent tumor nuclei: 85; Percent necrosis: 7.
- Sample C3N-03025-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -14 days; Method of sample procurement: Blood Draw.
